Somatic mutation profile of tumor specimen TARGET-10-PAPZUW-09A (aliquot TARGET-10-PAPZUW-09A-01D) from TARGET case TARGET-10-PAPZUW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,329 days).
Specimen TARGET-10-PAPZUW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1ab9b4e-1409-4f0b-b3e4-5141813591a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPZUW-10A (Blood Derived Normal), aliquot TARGET-10-PAPZUW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73a84f1a-9118-41c4-98e8-235f95d950ee

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Nonsense Mutation 2, Intron 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL11A1 | c.3541C>T p.Q1181* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV62195454; called by muse, mutect2, varscan2
- MYCBP2 | c.8854C>T p.R2952* (on ENST00000357337; = p.R2990* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 45/114 reads (39%) | catalogued as COSV62022493, COSV62032185; called by muse, mutect2, varscan2
- SCN2B | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs370514575, COSV99635978; called by muse, mutect2, varscan2
- DOCK4 | c.1039C>A p.R347S | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- PPIL2 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PUS7L | c.1792G>A p.V598I | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STOX2 | c.906G>A p.T302= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as rs373037028, COSV100409060; called by muse, mutect2, varscan2
- TAF1L | c.5478A>G p.K1826= | Silent (SNP) | VAF 52/75 reads (69%) | catalogued as rs1244624398; called by muse, mutect2, varscan2
- CHN1 | c.59-239G>A | Intron (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- STKLD1 | c.584-74G>A | Intron (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
